Somatic mutation profile of tumor specimen TCGA-DX-AB2S-01A (aliquot TCGA-DX-AB2S-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2S, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 54.0 years (19,708 days).
Specimen TCGA-DX-AB2S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2592e6a-0078-45af-b04e-26c94bd5e2d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2S-10A (Blood Derived Normal), aliquot TCGA-DX-AB2S-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/385bff08-6d8f-4b9b-8177-fdea66cfb900

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRNR | c.7024G>C p.G2342R | Missense Mutation (SNP) | VAF 146/634 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV100912874; called by muse, varscan2
- LRIG3 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100292394; called by muse, mutect2
- OGT | c.2592T>A p.I864= | Splice Region (SNP) | VAF 11/144 reads (8%) | catalogued as COSV101035142, COSV101035168; called by muse, mutect2
- OR2AG1 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100264805; called by muse, mutect2, varscan2
- PHF3 | c.1965T>G p.F655L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100012838; called by muse, mutect2
- QDPR | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1303472425, COSV99845657; called by muse, mutect2, varscan2
- SQLE | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99772080; called by muse, mutect2
- ZNF318 | c.1499C>G p.A500G | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100545924; called by muse, mutect2
- ZNF382 | c.306A>G p.I102M | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV99497397; called by muse, mutect2
- AL133500.1 | c.1566G>A p.A522= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as rs1421694446, COSV55745236, COSV99860261; called by muse, mutect2
- LAMB1 | c.3766C>T p.L1256= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1267186707, COSV99739774; called by muse, mutect2, varscan2
